Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7690, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7690-01A (Primary Tumor).

Microscopic

Sections demonstrate a mildly to markedly hypercellular glial neoplasm that diffusely infiltrates both gray and white matter. The neoplastic cells range from microgemistocytis to ordinary gemistocytes and many have round nuclei with prominent perinuclear halos. Atypia is moderate. Neither microvascular proliferation nor necrosis is seen. However, up to nine mitoses are seen in 10 high power fields.

Diagnosis

Anaplastic oligoastrocytoma, oligodendroglioma predominant grade III

Source: NCI Genomic Data Commons file 81e17333-77f2-4e9c-8ee0-50ee8182230a (TCGA-HT-7690.CC74DDE4-33C1-4A77-A773-970C0F1ED142.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).